Somatic mutation profile of tumor specimen TCGA-CV-A45P-01A (aliquot TCGA-CV-A45P-01A-11D-A24D-08) from TCGA case TCGA-CV-A45P, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 82.9 years (30,297 days).
Specimen TCGA-CV-A45P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be8d69e4-ddd7-48e5-b3e0-cbb637b22a04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45P-10A (Blood Derived Normal), aliquot TCGA-CV-A45P-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ef8075-1644-4812-8fbb-94cdbd81816f

The open-access MAF lists 165 somatic variants for this specimen: 121 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 40, Nonsense Mutation 8, Splice Site 3, RNA 2, Intron 2, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, varscan2
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB1 | c.804C>G p.F268L (on ENST00000232744 / NM_172027.3; = p.F126L on NM_032548.3) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99229489; called by muse, mutect2, varscan2
- AC011462.1 | c.657G>C p.L219F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1270056543, COSV99524356; called by muse, mutect2, varscan2
- ACOT2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs1174727774, COSV99468684; called by muse, mutect2, varscan2
- ADGRA3 | c.3462C>A p.H1154Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99292785; called by muse, mutect2, varscan2
- ALPK3 | c.4769G>A p.R1590Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs1432141737, COSV51930797; called by muse, mutect2, varscan2
- ARFGEF1 | c.2723G>C p.R908T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51604942, COSV99144913; called by muse, mutect2, varscan2
- ARMCX5 | c.730C>G p.P244A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as COSV99863238; called by muse, mutect2, varscan2
- ATG14 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs556057378, COSV99902525; called by muse, mutect2
- ATP4A | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52869438, COSV99381947; called by muse, mutect2, varscan2
- CASP8 | c.1237C>T p.R413* (on ENST00000432109 / NM_033355.3; = p.R430* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1272714323, COSV51845663; called by muse, mutect2, varscan2
- CCDC60 | c.1608G>C p.Q536H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100554424; called by muse, mutect2, varscan2
- CCDC86 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.658); catalogued as rs1289416008, COSV99920007; called by muse, mutect2, varscan2
- CCDC9B | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs548213771, COSV101233461; called by muse, mutect2, varscan2
- CCIN | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs765562220, COSV58725046; called by muse, mutect2, varscan2
- CDHR2 | c.2501C>T p.S834L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as rs766703295, COSV56134491, COSV56137216; called by muse, mutect2, varscan2
- CEP192 | c.3998C>T p.S1333F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs774167042, COSV100380368; called by muse, mutect2, varscan2
- CHD8 | c.6632C>G p.S2211C (on ENST00000646647 / NM_001170629.2; = p.S1932C on NM_020920.4) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV100765229; called by muse, mutect2, varscan2
- COL4A2 | c.4229G>A p.R1410Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.19); catalogued as rs1004346642, COSV64629756; called by muse, mutect2
- CPNE8 | c.764T>A p.L255H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100503627; called by muse, mutect2, varscan2
- CRYZL1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV99280774; called by muse, mutect2, varscan2
- CSAD | c.648-1G>A p.X216_splice (on ENST00000444623 / NM_001244705.2; = p.X243_splice on NM_015989.5) | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99914392; called by muse, mutect2, varscan2
- CUL9 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99334497; called by muse, mutect2, varscan2
- CYP4F2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs750537115, COSV50001215; called by muse, mutect2, varscan2
- DIMT1 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.127); catalogued as rs768150911, COSV52233263; called by muse, mutect2
- DLG4 | c.46G>C p.D16H (on ENST00000399506 / NM_001321075.3; = p.D59H on NM_001365.4) | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100263318; called by muse, mutect2, varscan2
- DMXL2 | c.7325G>C p.R2442T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV99195900; called by muse, mutect2, varscan2
- DNAAF4 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV100336497; called by muse, mutect2
- DNAH2 | c.7850G>C p.R2617P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101208912, COSV66723042; called by muse, mutect2, varscan2
- DOCK7 | c.4103C>G p.S1368C (on ENST00000635253 / NM_001367561.1; = p.S1337C on NM_033407.3) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99222215; called by muse, mutect2, varscan2
- DOHH | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202024004, COSV99170967, COSV99171082; called by muse, mutect2, varscan2
- DSE | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100528234; called by muse, mutect2, varscan2
- EIF2AK3 | c.2411C>A p.S804Y | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100303257; called by muse, mutect2, varscan2
- EMC8 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs376195354; called by muse, mutect2
- FKBP5 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs751820100, COSV100615943; called by muse, mutect2, varscan2
- FLNA | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs1569551740, COSV61048076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRY | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV66573976; called by muse, mutect2, varscan2
- GABRE | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs61740527, COSV100944190, COSV100944387; called by muse, mutect2, varscan2
- GDAP2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1358657059, COSV101032201; called by muse, mutect2
- GPR137 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as rs138261831, COSV100463799; called by muse, mutect2, varscan2
- GRIN2D | c.2239C>G p.Q747E | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV99615641; called by muse, mutect2, varscan2
- GYG2 | c.1155G>C p.E385D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as COSV100088527; called by muse, mutect2, varscan2
- H6PD | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV101072393; called by muse, mutect2
- HERC2 | c.11675C>A p.P3892Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV55309986, COSV99869767; called by muse, mutect2
- HINFP | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100640800; called by muse, mutect2, varscan2
- HNF1A | c.1640C>G p.T547S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV99981821; called by muse, mutect2, varscan2
- HSF4 | c.1120G>C p.E374Q (on ENST00000521374 / NM_001040667.3; = p.E344Q on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV50457630, COSV99263355; called by muse, varscan2
- IFNA21 | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV101207406, COSV66518452; called by muse, mutect2, varscan2
- IGBP1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100642850; called by muse, mutect2, varscan2
- INTS6 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1324048232, COSV100246828; called by muse, mutect2, varscan2
- ITGA10 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs587701227, COSV65198194; called by muse, mutect2, varscan2
- KCNU1 | c.3367G>C p.G1123R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV101298699; called by muse, mutect2, varscan2
- KDM4A | c.2897G>C p.R966T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99494652; called by muse, mutect2, varscan2
- KIF3C | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs1489392281, COSV53099589; called by muse, mutect2, varscan2
- LONP2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462892903, COSV99588675; called by muse, mutect2, varscan2
- LRRK2 | c.4112T>A p.I1371K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100108572; called by muse, mutect2, varscan2
- MAP7 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100643633; called by muse, mutect2
- MDC1 | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV100902410, COSV100902854; called by muse, mutect2, varscan2
- MDGA2 | c.1361G>A p.R454Q (on ENST00000399232 / NM_001113498.2; = p.R156Q on NM_182830.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771715302, COSV62115855; called by muse, mutect2, varscan2
- MED30 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV99815872; called by muse, mutect2, varscan2
- MIS18BP1 | c.948G>C p.Q316H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as rs1455229565, COSV100172523; called by muse, mutect2, varscan2
- MLLT10 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV100307113; called by muse, mutect2, varscan2
- MMP2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as rs200271857, COSV99527282; called by muse, mutect2, varscan2
- MTFR1L | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.762); catalogued as COSV100961766; called by muse, mutect2
- MUC16 | c.16526C>G p.S5509C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1233138651, COSV101197314; called by muse, mutect2, varscan2
- MYH10 | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99343722; called by muse, mutect2, varscan2
- NLGN4X | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs749422843, COSV99319324; called by muse, mutect2, varscan2
- NOL8 | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100694383; called by muse, mutect2, varscan2
- NOTCH2 | c.1379G>T p.C460F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99862289; called by muse, mutect2, varscan2
- NPSR1 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100705570, COSV100707047, COSV62202411; called by muse, mutect2, varscan2
- NUDCD1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV99516508; called by muse, mutect2, varscan2
- NXF1 | c.1014C>T p.I338= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99585645; called by muse, mutect2, varscan2
- PALLD | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250369065, COSV99823536; called by muse, mutect2, varscan2
- PCDHB10 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as rs782146539, COSV99503465; called by muse, mutect2, varscan2
- PCDHGA4 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV99528000; called by muse, mutect2, varscan2
- PCGF6 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV100461579; called by muse, mutect2
- PEDS1 | c.646A>T p.I216F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100501769; called by muse, mutect2, varscan2
- PFDN6 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101004693; called by muse, mutect2, varscan2
- POU4F2 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs766646381, COSV55585975; called by muse, mutect2, varscan2
- PRDM9 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs375716818; called by muse, mutect2, varscan2
- PRKCE | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100076121, COSV100077357; called by muse, mutect2, varscan2
- PRLR | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs139147779; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by mutect2, varscan2
- RAI14 | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99461369; called by muse, mutect2, varscan2
- RALBP1 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99191859; called by mutect2, varscan2
- RPGRIP1 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM078811, COSV99250184; called by muse, mutect2, varscan2
- RSAD1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as COSV99364062; called by muse, mutect2, varscan2
- SCAP | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99652275; called by muse, mutect2, varscan2
- SH2D3A | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV99837718; called by muse, mutect2
- SIN3B | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.014); catalogued as COSV56130850, COSV99931275; called by muse, mutect2, varscan2
- SLC26A2 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV53824286, COSV99639903; called by muse, mutect2, varscan2
- SLC34A1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV100183704; called by muse, mutect2, varscan2
- SLC6A3 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs773100141, COSV54362035; called by muse, mutect2
- SLX4IP | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.54); catalogued as COSV100570089; called by muse, mutect2, varscan2
- SMPDL3B | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100875247; called by muse, mutect2, varscan2
- SRGAP3 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs775488458, COSV100840581; called by muse, mutect2, varscan2
- STAG3 | c.2327G>A p.R776K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100425464, COSV57928984; called by muse, mutect2, varscan2
- STK3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.174); catalogued as COSV101372399; called by mutect2, varscan2
- STK32B | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283660; called by muse, mutect2, varscan2
- STXBP4 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54842646; called by muse, mutect2, varscan2
- SYNE2 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100646337; called by muse, mutect2, varscan2
- TACC3 | c.163-1G>C p.X55_splice | Splice Site (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100304903; called by muse, mutect2, varscan2
- TAPT1 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs749192598, COSV58824417; called by muse, mutect2, varscan2
- TBC1D4 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.197); catalogued as COSV100884427; called by muse, mutect2, varscan2
- TC2N | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100562651; called by muse, mutect2, varscan2
- TCL1A | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101268432; called by muse, mutect2, varscan2
- TGFBR2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM064336, COSV55442699; called by muse, mutect2
- TMEM63A | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV100834192; called by muse, mutect2, varscan2
- TNC | c.3772G>A p.D1258N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.185); catalogued as COSV100404683; called by muse, mutect2, varscan2
- TP53 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.4174C>T p.R1392C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs143272455; called by muse, mutect2
- USP16 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV54506323, COSV99725763; called by muse, mutect2, varscan2
- UTP14A | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100928912; called by muse, mutect2, varscan2
- VSIG2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768117045, COSV99422975; called by muse, mutect2, varscan2
- ZC3H12B | c.1640C>G p.S547* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100161394; called by muse, mutect2, varscan2
- ZGPAT | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100157315; called by muse, mutect2, varscan2
- ZNF185 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV100248087; called by muse, mutect2, varscan2
- CUL7 | c.1222_1233+7del p.X408_splice | Splice Site (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- SUGP2 | c.1799del p.G600Afs*33 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- TAS1R1 | c.1685dup p.L562Ffs*3 | Frame Shift Ins (INS) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- ABCB1 | c.603C>T p.F201= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99711773; called by muse, mutect2, varscan2
- ADO | c.144C>T p.P48= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101060394; called by muse, mutect2, varscan2
- ANKRD30A | c.864G>A p.A288= (on ENST00000611781; = p.A232= on NM_052997.2) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs369194109, COSV64602846, COSV64610666; called by muse, mutect2, varscan2
- AP5Z1 | c.1632C>T p.A544= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs373183061; called by muse, mutect2
- ARHGAP31 | c.2703C>A p.G901= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV99956386; called by muse, mutect2, varscan2
- ARHGDIA | c.348C>T p.F116= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV53907258; called by muse, varscan2
- ARID1B | c.6207G>T p.V2069= | Silent (SNP) | VAF 58/235 reads (25%) | catalogued as rs1034348028, COSV99266431; called by muse, mutect2, varscan2
- BCL9L | c.3987C>A p.I1329= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99418301; called by muse, mutect2, varscan2
- CCM2L | c.141C>T p.P47= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as rs752732555, COSV52949374, COSV52950272; called by muse, mutect2, varscan2
- CEP83 | c.1074C>G p.L358= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100352543; called by muse, mutect2, varscan2
- CLDN16 | c.348C>T p.I116= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99289882; called by muse, mutect2, varscan2
- COL4A6 | c.3969G>T p.L1323= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100563028; called by muse, mutect2, varscan2
- DAZAP1 | c.621G>A p.G207= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99244902; called by muse, mutect2, varscan2
- DNAJC5G | c.282C>T p.Y94= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs750432820, COSV99940468; called by muse, mutect2, varscan2
- EPG5 | c.5613C>T p.S1871= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV99956197; called by muse, mutect2, varscan2
- EPHB1 | c.2184C>A p.I728= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV101212468; called by muse, mutect2, varscan2
- ERAP2 | c.1536A>G p.G512= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV101163413; called by muse, mutect2, varscan2
- HES1 | c.300G>A p.L100= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99220198; called by muse, mutect2, varscan2
- IFT43 | c.417C>G p.L139= (on ENST00000314067 / NM_001102564.3; = p.L144= on NM_052873.3) | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99465400; called by muse, mutect2, varscan2
- IL2RG | c.57G>T p.L19= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99339994; called by muse, mutect2
- MCM5 | c.462C>T p.I154= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1005496884, COSV99331386; called by muse, mutect2, varscan2
- MMP2 | c.369G>A p.Q123= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99527279; called by mutect2, varscan2
- MNDA | c.1122G>A p.L374= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs560794903, COSV100933217, COSV63741706; called by muse, mutect2, varscan2
- MYLK3 | c.1731C>T p.D577= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs747900006, COSV67362842; called by muse, mutect2, varscan2
- PARPBP | c.951C>T p.I317= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100568912; called by muse, mutect2, varscan2
- PIK3CB | c.1089C>T p.L363= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100005076; called by muse, mutect2, varscan2
- PLEKHF2 | c.402C>T p.L134= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1563884820, COSV100193285; called by muse, mutect2, varscan2
- RGS18 | c.579G>A p.L193= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV66508064; called by muse, mutect2, varscan2
- RTP1 | c.756C>T p.I252= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs1457181620, COSV100398629; called by muse, mutect2, varscan2
- SNX29 | c.1254C>T p.L418= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs183275123, COSV100026780; called by muse, mutect2, varscan2
- SYNDIG1L | c.660C>G p.L220= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100526315, COSV59047705; called by muse, mutect2, varscan2
- TAFA5 | c.213A>G p.R71= (on ENST00000402357 / NM_001082967.3; = p.R64= on NM_015381.7) | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100384845; called by muse, mutect2
- TBX6 | c.759G>A p.Q253= | Silent (SNP) | VAF 34/213 reads (16%) | catalogued as COSV99661385; called by muse, mutect2, varscan2
- WNT3A | c.186C>T p.I62= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99468565; called by muse, mutect2, varscan2
- ZBTB4 | c.2589C>T p.S863= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1487790810, COSV100043351; called by muse, mutect2, varscan2
- ZBTB40 | c.3081C>A p.T1027= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100988766; called by muse, mutect2, varscan2
- ZFP42 | c.15G>A p.L5= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs766584896, COSV58818132; called by muse, mutect2, varscan2
- ZMYM6 | c.342C>G p.L114= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100451511; called by muse, mutect2, varscan2
- ZNF248 | c.1524T>A p.I508= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100627433; called by muse, mutect2, varscan2
- ZNF296 | c.855G>A p.P285= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as rs749505047, COSV99673379; called by muse, mutect2, varscan2
- MGAM | c.4618+5605G>T | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101527327, COSV101527593; called by muse, mutect2, varscan2
- MIR516A2 | n.21G>C | RNA (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- NBPF25P | n.819G>A | RNA (SNP) | VAF 27/219 reads (12%) | catalogued as rs1464124900; called by muse, mutect2, varscan2
- SKA2 | c.33+126C>T | Intron (SNP) | VAF 14/87 reads (16%) | catalogued as rs1040188833, COSV99231233; called by muse, mutect2, varscan2
